Somatic mutation profile of tumor specimen HCM-CSHL-0512-C24-06A (aliquot HCM-CSHL-0512-C24-06A-21D-A82H-36) from HCMI case HCM-CSHL-0512-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 76.0 years (27,746 days).
Specimen HCM-CSHL-0512-C24-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 035107a7-5335-425b-8b1b-989930a9983f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0512-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0512-C24-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e77a678-ef74-4fe8-a2f0-03b76b3b914a

The open-access MAF lists 94 somatic variants for this specimen: 65 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 28, Frame Shift Ins 4, Nonsense Mutation 3, Splice Region 1, Splice Site 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 106/359 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs376872688; called by muse, mutect2, varscan2
- ADH1B | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs187446108, COSV104396458; called by muse, mutect2, varscan2
- ALMS1 | c.1484C>G p.S495* | Nonsense Mutation (SNP) | VAF 59/337 reads (18%) | catalogued as COSV100042003, COSV52520271; called by muse, mutect2, varscan2
- BAP1 | c.1538C>G p.S513* | Nonsense Mutation (SNP) | VAF 110/392 reads (28%) | catalogued as COSV56229978; called by muse, mutect2, varscan2
- CHUK | c.1519dup p.M507Nfs*17 | Frame Shift Ins (INS) | VAF 38/184 reads (21%) | catalogued as rs1564833034; called by mutect2, pindel, varscan2
- CLIP2 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 120/551 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs1554312777; called by muse, mutect2, varscan2
- CNGB3 | c.2383G>A p.G795R | Missense Mutation (SNP) | VAF 66/363 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs753083465, CM122538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD1 | c.5144G>A p.R1715Q (on ENST00000520002; = p.R1714Q on NM_033225.6) | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs747749324, COSV59310534; called by muse, mutect2, varscan2
- DHRS7 | c.819G>T p.M273I | Missense Mutation (SNP) | VAF 92/429 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV53665397; called by muse, mutect2, varscan2
- EGF | c.3124G>A p.V1042M | Missense Mutation (SNP) | VAF 81/490 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs376152924; called by muse, mutect2, varscan2
- ELL | c.22A>G p.R8G | Missense Mutation (SNP) | VAF 95/376 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.247); catalogued as rs781430794; called by muse, mutect2, varscan2
- GRIP1 | c.1490T>C p.L497P (on ENST00000359742 / NM_001379345.1; = p.L445P on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/1087 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99668079; called by muse, mutect2
- KMT2C | c.3420G>A p.M1140I | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs573946244; called by muse, mutect2, varscan2
- MMP19 | c.1271del p.G424Efs*10 | Frame Shift Del (DEL) | VAF 94/947 reads (10%) | catalogued as COSV59452344; called by mutect2, pindel
- OBSL1 | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 133/742 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.065); catalogued as rs527421647; called by muse, mutect2, varscan2
- RBAK | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1400837238; called by muse, mutect2, varscan2
- SH3D19 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 67/366 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.855); catalogued as COSV58792566; called by muse, mutect2, varscan2
- SIGLEC5 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 99/653 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs756464645; called by muse, mutect2, varscan2
- SLC2A14 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 68/332 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as rs766018281, COSV61586599; called by muse, mutect2, varscan2
- SLC39A12 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782725317, COSV101069963, COSV66194871; called by muse, mutect2, varscan2
- TLR1 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 62/300 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58303672; called by muse, mutect2, varscan2
- UBXN1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 105/631 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.151); catalogued as rs368902441; called by muse, mutect2, varscan2
- ZNF785 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 94/543 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs201848622, COSV67876261; called by muse, mutect2, varscan2
- ADGRV1 | c.4825T>G p.F1609V | Missense Mutation (SNP) | VAF 123/514 reads (24%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ARMC10 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 50/414 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2
- ATP4B | c.510C>A p.F170L | Missense Mutation (SNP) | VAF 68/473 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- C6 | c.2005G>C p.E669Q | Missense Mutation (SNP) | VAF 55/321 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CAMKK2 | c.1011C>G p.F337L | Missense Mutation (SNP) | VAF 131/438 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CFAP61 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 74/357 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CLASP2 | c.2062C>G p.Q688E | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- CLDN15 | c.582C>T p.S194= | Splice Region (SNP) | VAF 92/404 reads (23%) | called by muse, mutect2
- DFFB | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 128/631 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- DMBX1 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 116/489 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DOP1A | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EXPH5 | c.3251T>G p.V1084G | Missense Mutation (SNP) | VAF 64/426 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- EXPH5 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- FUT10 | c.478C>G p.H160D | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- GAD2 | c.921-1G>C p.X307_splice | Splice Site (SNP) | VAF 24/146 reads (16%) | called by mutect2, varscan2
- GALNT15 | c.1132A>T p.N378Y | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- GOLGA6L7 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITIH6 | c.1897A>T p.I633F | Missense Mutation (SNP) | VAF 122/570 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- LRFN4 | c.892dup p.A298Gfs*10 | Frame Shift Ins (INS) | VAF 101/667 reads (15%) | called by mutect2, pindel, varscan2
- LSM5 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LY75 | c.3225G>T p.W1075C | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAN2A2 | c.3272G>A p.G1091D | Missense Mutation (SNP) | VAF 67/406 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- MCF2L2 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 53/336 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- MRPS15 | c.438T>G p.H146Q | Missense Mutation (SNP) | VAF 73/365 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- MYH3 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NDUFS2 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 62/363 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NIN | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 81/448 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR2G3 | c.333A>C p.E111D | Missense Mutation (SNP) | VAF 79/414 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2M7 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 49/301 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR2T11 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 80/408 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.3404C>G p.S1135C | Missense Mutation (SNP) | VAF 74/389 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- PLCL1 | c.3038A>T p.E1013V | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- RASGRF2 | c.3093G>C p.W1031C | Missense Mutation (SNP) | VAF 49/278 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RIMKLB | c.654dup p.R219Tfs*25 | Frame Shift Ins (INS) | VAF 69/425 reads (16%) | called by mutect2, pindel, varscan2
- SPTA1 | c.4828C>T p.Q1610* | Nonsense Mutation (SNP) | VAF 82/395 reads (21%) | called by muse, mutect2, varscan2
- TIAF1 | c.211G>C p.V71L | Missense Mutation (SNP) | VAF 18/522 reads (3%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.111); called by muse, mutect2
- XK | c.119C>G p.T40R | Missense Mutation (SNP) | VAF 105/549 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZAN | c.2270A>T p.E757V | Missense Mutation (SNP) | VAF 85/530 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- ZNF461 | c.634dup p.R212Kfs*5 | Frame Shift Ins (INS) | VAF 23/159 reads (14%) | called by mutect2, pindel, varscan2
- ZNF608 | c.3341T>A p.L1114Q | Missense Mutation (SNP) | VAF 99/498 reads (20%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ZNF835 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 111/535 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- ACSBG1 | c.435C>T p.A145= | Silent (SNP) | VAF 42/290 reads (14%) | catalogued as rs370940723; called by muse, varscan2
- ANO3 | c.702C>T p.C234= | Silent (SNP) | VAF 55/270 reads (20%) | called by muse, varscan2
- BAIAP3 | c.852G>A p.V284= | Silent (SNP) | VAF 70/336 reads (21%) | catalogued as rs1204243439; called by muse, mutect2, varscan2
- BHLHE22 | c.399G>A p.A133= | Silent (SNP) | VAF 156/781 reads (20%) | catalogued as COSV58861182; called by muse, varscan2
- DOT1L | c.2535C>T p.S845= | Silent (SNP) | VAF 75/305 reads (25%) | called by muse, mutect2, varscan2
- DRC1 | c.528C>T p.S176= | Silent (SNP) | VAF 34/276 reads (12%) | catalogued as rs780717600; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHB1 | c.1641G>A p.A547= | Silent (SNP) | VAF 53/320 reads (17%) | catalogued as rs776531462, COSV101212909, COSV67670208; called by muse, mutect2, varscan2
- F7 | c.1053C>T p.G351= | Silent (SNP) | VAF 115/533 reads (22%) | catalogued as rs140590804; called by muse, mutect2, varscan2
- FUT10 | c.1011C>T p.I337= | Silent (SNP) | VAF 70/295 reads (24%) | catalogued as COSV59450565; called by muse, mutect2, varscan2
- HTRA2 | c.498C>T p.I166= | Silent (SNP) | VAF 77/348 reads (22%) | catalogued as rs1194234722; called by muse, mutect2, varscan2
- IGSF1 | c.1461C>T p.R487= | Silent (SNP) | VAF 111/540 reads (21%) | catalogued as rs149158944, COSV63840446; called by muse, mutect2, varscan2
- KCND1 | c.600C>G p.V200= | Silent (SNP) | VAF 135/641 reads (21%) | called by muse, mutect2, varscan2
- LIPE | c.1554C>T p.I518= | Silent (SNP) | VAF 100/483 reads (21%) | catalogued as rs1338293260; called by muse, mutect2, varscan2
- MLPH | c.567C>T p.L189= | Silent (SNP) | VAF 52/310 reads (17%) | catalogued as COSV52820603; called by muse, mutect2, varscan2
- MRPS27 | c.1170C>A p.I390= | Silent (SNP) | VAF 92/385 reads (24%) | called by muse, mutect2, varscan2
- NALCN | c.2514C>T p.F838= | Silent (SNP) | VAF 97/448 reads (22%) | catalogued as rs200716691; ClinVar: likely benign; called by muse, mutect2, varscan2
- NF1 | c.4503C>T p.D1501= (on ENST00000358273 / NM_001042492.3; = p.D1480= on NM_000267.3) | Silent (SNP) | VAF 61/407 reads (15%) | catalogued as rs577394398; ClinVar: likely benign; called by muse, mutect2, varscan2
- PYGB | c.1251G>A p.A417= | Silent (SNP) | VAF 69/333 reads (21%) | catalogued as rs767274675; called by muse, mutect2, varscan2
- RYR3 | c.192C>T p.C64= | Silent (SNP) | VAF 51/285 reads (18%) | catalogued as rs769694918, COSV66784372; called by muse, mutect2, varscan2
- SIGLEC5 | c.315C>T p.I105= | Silent (SNP) | VAF 54/332 reads (16%) | catalogued as rs1371382400; called by muse, mutect2, varscan2
- SLC4A10 | c.891T>C p.S297= | Silent (SNP) | VAF 54/264 reads (20%) | called by muse, mutect2, varscan2
- TMEM271 | c.1077C>T p.P359= | Silent (SNP) | VAF 139/731 reads (19%) | catalogued as rs1170271441; called by muse, mutect2, varscan2
- TMEM271 | c.996C>T p.H332= | Silent (SNP) | VAF 127/769 reads (17%) | called by muse, mutect2, varscan2
- TNFRSF8 | c.1356G>A p.S452= | Silent (SNP) | VAF 17/372 reads (5%) | catalogued as rs1006794023; called by muse, mutect2
- TSPYL1 | c.540G>C p.L180= | Silent (SNP) | VAF 106/455 reads (23%) | called by muse, mutect2, varscan2
- UPF1 | c.1629G>A p.E543= (on ENST00000599848 / NM_001297549.2; = p.E532= on NM_002911.4) | Silent (SNP) | VAF 135/417 reads (32%) | catalogued as rs1455466301; called by muse, mutect2, varscan2
- WDFY3 | c.8604A>G p.K2868= | Silent (SNP) | VAF 43/220 reads (20%) | called by muse, mutect2, varscan2
- ZMIZ1 | c.2724G>A p.G908= | Silent (SNP) | VAF 165/731 reads (23%) | catalogued as rs1204223303; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-9546T>G | Intron (SNP) | VAF 77/330 reads (23%) | called by muse, mutect2, varscan2
